Somatic mutation profile of tumor specimen TCGA-CV-6942-01A (aliquot TCGA-CV-6942-01A-21D-2012-08) from TCGA case TCGA-CV-6942, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.8 years (26,941 days).
Specimen TCGA-CV-6942-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ad2c2e-0582-415c-8ec3-7cdb0b02a55a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6942-10A (Blood Derived Normal), aliquot TCGA-CV-6942-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ece2df7d-3d94-4675-8112-b526325d3bb4

The open-access MAF lists 241 somatic variants for this specimen: 183 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 55, Nonsense Mutation 15, Splice Site 5, Frame Shift Del 5, Intron 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFT140 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387907192, CM123472, COSV68487441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as rs1563831738, COSV51489245, COSV51505728; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598777, COSV100933169; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0); catalogued as rs773242958, COSV99865371; called by muse, mutect2, varscan2
- ACSL4 | c.262T>A p.S88T (on ENST00000340800 / NM_022977.2; = p.S47T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100538766; called by muse, mutect2, varscan2
- ADAMTS15 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs560827134, COSV100143589; called by muse, mutect2, varscan2
- AHI1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 37/146 reads (25%) | catalogued as COSV99663196; called by muse, mutect2, varscan2
- ALDH9A1 | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100699314; called by muse, mutect2, varscan2
- ALOX12 | c.1149C>A p.H383Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99278235; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99781963; called by muse, mutect2
- ANKRD12 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1189927663, COSV100041678; called by muse, mutect2, varscan2
- APOB | c.9371A>G p.D3124G | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99266627; called by muse, mutect2, varscan2
- APOBEC1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV99981154; called by muse, mutect2, varscan2
- AQR | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as COSV99334300; called by muse, mutect2, varscan2
- ARHGAP29 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs747148271, COSV99557828; called by muse, mutect2, varscan2
- ARHGAP4 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as COSV100604119; called by muse, mutect2, varscan2
- ARHGAP6 | c.1468A>G p.I490V | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as rs147456861, COSV100273250; called by muse, mutect2, varscan2
- ASIC5 | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV101611153; called by muse, mutect2, varscan2
- ATG16L1 | c.964G>A p.D322N (on ENST00000392017 / NM_030803.7; = p.D303N on NM_017974.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100731345; called by muse, mutect2, varscan2
- ATN1 | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.285); catalogued as COSV63110961; called by muse, mutect2, varscan2
- ATP11C | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.686); catalogued as COSV100558268; called by muse, mutect2, varscan2
- ATP8A1 | c.3397+1G>A p.X1133_splice | Splice Site (SNP) | VAF 24/114 reads (21%) | catalogued as rs778155403, COSV100046680; called by muse, mutect2, varscan2
- AURKC | c.892C>T p.R298* (on ENST00000302804 / NM_001015878.2; = p.R264* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as rs1373200287, COSV100248791; called by muse, mutect2, varscan2
- BCL11A | c.2241G>C p.Q747H (on ENST00000335712 / NM_001365609.1; = p.Q781H on NM_022893.4) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100186025; called by muse, mutect2, varscan2
- BMP7 | c.959-1G>C p.X320_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV101216093; called by muse, mutect2, varscan2
- C9orf152 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs753779115, COSV68762819; called by muse, mutect2, varscan2
- CATSPER3 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99254228; called by muse, mutect2, varscan2
- CDADC1 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51912669; called by muse, mutect2, varscan2
- CDH17 | c.1546A>T p.K516* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99217701; called by muse, mutect2
- CDKN2A | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs1563892532, COSV100447081, COSV58696672, COSV58713866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR1 | c.6768C>A p.F2256L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV53098938, COSV99419045; called by muse, mutect2, varscan2
- CFAP44 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.04); catalogued as COSV99870004; called by muse, mutect2, varscan2
- CFTR | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99137686; called by muse, mutect2, varscan2
- CLEC4F | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.225); catalogued as rs1033411670, COSV99713856; called by muse, mutect2, varscan2
- CNNM2 | c.446G>C p.R149P | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100881739, COSV100881746; called by muse, mutect2, varscan2
- COL1A2 | c.3514G>C p.E1172Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as COSV99800380; called by muse, mutect2
- COQ5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.213); catalogued as COSV99942396; called by muse, mutect2, varscan2
- CTSF | c.1274G>T p.S425I | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100074373; called by muse, mutect2, varscan2
- CXCR2 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100579018; called by muse, varscan2
- CYP27B1 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs549824639, COSV99141599; called by muse, mutect2, varscan2
- CYP2C19 | c.781C>G p.R261G | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM1510885, COSV100990568, COSV64907403; called by muse, mutect2, varscan2
- DAPK1 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 37/191 reads (19%) | catalogued as rs1276428726, COSV63785483; called by muse, mutect2, varscan2
- DPYD | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100929223; called by muse, mutect2, varscan2
- DUSP6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.51); catalogued as COSV99684078; called by muse, mutect2, varscan2
- EHBP1L1 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100499948; called by muse, mutect2
- EIF3M | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.544); catalogued as COSV100025075; called by muse, mutect2, varscan2
- EIF4G1 | c.764C>T p.S255L (on ENST00000346169 / NM_198241.3; = p.S59L on NM_004953.5) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV59995582; called by muse, mutect2, varscan2
- EPCAM | c.533C>A p.P178Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55394465, COSV99764241; called by muse, mutect2, varscan2
- ERAS | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV99504866; called by muse, mutect2, varscan2
- FAM89A | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100792622; called by muse, mutect2, varscan2
- FEZF1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100484519; called by muse, mutect2, varscan2
- FHOD1 | c.374-1G>A p.X125_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99264296; called by muse, mutect2
- FOLH1 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | catalogued as COSV99923531; called by muse, mutect2
- FOXJ3 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100692019; called by muse, mutect2, varscan2
- GAL3ST4 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766188075, COSV100385569; called by muse, mutect2, varscan2
- GAS2L2 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1353957409; called by muse, mutect2, varscan2
- GCNA | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV101032596; called by muse, mutect2, varscan2
- GLI1 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs758959112, COSV99953638; called by muse, mutect2, varscan2
- GNAL | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV52329015, COSV52334061; called by muse, mutect2, varscan2
- H2BC9 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV55099788, COSV55100388; called by muse, mutect2, varscan2
- HFM1 | c.4154C>G p.S1385C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.635); catalogued as rs190831701, COSV54025309, COSV99646334; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1842G>C p.E614D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100079716; called by muse, mutect2
- HS6ST1 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV99389745; called by muse, mutect2, varscan2
- HSPD1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV52100163; called by muse, mutect2, varscan2
- IGKV2D-29 | c.181T>A p.Y61N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV101534387; called by muse, varscan2
- IGKV2D-29 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV101534388; called by muse, varscan2
- IGKV3-11 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs183365521; called by muse, mutect2, varscan2
- IL18R1 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52125509; called by muse, mutect2, varscan2
- IL4I1 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV55580197; called by muse, mutect2
- ILDR2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs201864196, COSV54831468; called by muse, mutect2, varscan2
- INO80 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100731534, COSV100731944; called by muse, mutect2, varscan2
- INSRR | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751882198, COSV100947805; called by muse, mutect2, varscan2
- JARID2 | c.2788C>G p.R930G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100521588, COSV100522073; called by muse, mutect2, varscan2
- KIAA0319 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100985682, COSV65497046; called by muse, mutect2, varscan2
- LAMC3 | c.4698C>A p.S1566R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99908269; called by muse, mutect2, varscan2
- LAMC3 | c.4699C>A p.L1567M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99908270; called by muse, mutect2, varscan2
- LDLR | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM046148, COSV99370124; called by muse, mutect2, varscan2
- LIF | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV99969912; called by muse, mutect2, varscan2
- LLGL2 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV99389837, COSV99390090; called by muse, mutect2, varscan2
- LRRC37A | c.3812G>C p.R1271T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100208213; called by muse, mutect2, varscan2
- LRRC66 | c.2381C>G p.S794C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100603029, COSV58636941; called by muse, mutect2, varscan2
- LZTFL1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV99944853; called by muse, mutect2
- MACF1 | c.12260-1G>C p.X4087_splice (on ENST00000372915; = p.X2020_splice on NM_012090.5) | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99245652; called by muse, mutect2, varscan2
- MAGEC2 | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99909745, COSV99909797; called by muse, mutect2, varscan2
- MAN2B1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280493182, COSV54417563, COSV54417912; called by muse, mutect2, varscan2
- MAST4 | c.1501G>C p.E501Q (on ENST00000403625 / NM_001164664.2; = p.E312Q on NM_015183.3) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99844866; called by muse, mutect2, varscan2
- MCM3AP | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779630101, COSV52445284; called by muse, mutect2, varscan2
- MGAT5 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.993); catalogued as rs1297069775, COSV99924749; called by muse, mutect2, varscan2
- MTBP | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100012330; called by muse, mutect2, varscan2
- MUC5B | c.13571C>G p.A4524G | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV101500543; called by muse, mutect2, varscan2
- MX1 | c.1529G>C p.R510T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV99912747; called by muse, mutect2, varscan2
- MXRA5 | c.5660G>T p.W1887L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54237956; called by muse, mutect2, varscan2
- NAPSA | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.926); catalogued as COSV99515908; called by muse, mutect2, varscan2
- NBAS | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99870711; called by muse, mutect2, varscan2
- NCAM2 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99522627; called by muse, mutect2, varscan2
- NFE2L2 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67961697; called by muse, mutect2, varscan2
- NIN | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99814225; called by muse, mutect2, varscan2
- NLRP12 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs1347211586, COSV100145508, COSV100145597; called by muse, mutect2, varscan2
- NSD1 | c.7399G>C p.E2467Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV100729602; called by muse, mutect2, varscan2
- OGA | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100761908; called by muse, mutect2, varscan2
- OR5D13 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs369729738, COSV62332785; called by muse, mutect2, varscan2
- PASK | c.2357A>G p.E786G | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99299859; called by muse, mutect2, varscan2
- PCDH1 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.435); catalogued as COSV99746544; called by muse, mutect2, varscan2
- PCDHGB5 | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs375490385; called by muse, mutect2, varscan2
- PCLO | c.369G>C p.Q123H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV100434613; called by muse, mutect2, varscan2
- PEAK1 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100433239; called by muse, mutect2, varscan2
- PHACTR3 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100732849; called by muse, mutect2, varscan2
- PKDREJ | c.1711G>C p.A571P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV99479183; called by muse, mutect2, varscan2
- PLA2G4D | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.147); catalogued as COSV99299864; called by muse, mutect2, varscan2
- PLCB1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs866425965, COSV100569417, COSV62051786; called by muse, mutect2, varscan2
- PPP1R26 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.477); catalogued as COSV100778115; called by muse, mutect2, varscan2
- PPP2R3A | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.36); catalogued as COSV99387678; called by muse, mutect2, varscan2
- PRC1 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs529515389, COSV100727175; called by muse, mutect2, varscan2
- PTPRD | c.1150A>C p.S384R | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV100645627; called by muse, mutect2, varscan2
- PXDNL | c.4109C>G p.A1370G | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100684910, COSV62477078, COSV62496975; called by muse, mutect2, varscan2
- RAB23 | c.75G>T p.M25I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100443836; called by muse, mutect2, varscan2
- RABEP2 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs544986643, COSV100707133; called by muse, mutect2, varscan2
- RABL3 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99846574; called by muse, mutect2, varscan2
- RASA2 | c.1409C>G p.S470* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV53937692, COSV53938669; called by muse, mutect2, varscan2
- RBKS | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as COSV100142248; called by muse, mutect2, varscan2
- RIPK4 | c.1706G>A p.R569Q (on ENST00000352483; = p.R521Q on NM_020639.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs1238431406, COSV100205164; called by muse, mutect2, varscan2
- RMDN3 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99540133; called by muse, mutect2, varscan2
- SCN11A | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs1191368962, COSV100181967; called by muse, mutect2
- SIK3 | c.3568G>A p.E1190K (on ENST00000445177 / NM_001366686.2; = p.E1148K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV52624170, COSV99408395; called by muse, mutect2, varscan2
- SLC49A4 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99659158; called by muse, mutect2, varscan2
- SLC7A13 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99879038; called by muse, mutect2, varscan2
- SLCO1B1 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.734); catalogued as rs768916016, COSV99918772; called by muse, mutect2, varscan2
- SLITRK4 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as rs782295823, COSV100567070, COSV100567422, COSV62025137; called by muse, mutect2, varscan2
- SLX4 | c.579G>C p.L193F | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as COSV99568286; called by muse, mutect2, varscan2
- SORBS2 | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1339277863, COSV99511774; called by muse, mutect2, varscan2
- SOS2 | c.524T>G p.M175R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV99366406; called by muse, mutect2, varscan2
- SOX5 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100507458; called by muse, mutect2, varscan2
- SPEN | c.9986C>T p.S3329F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV101005418; called by muse, mutect2
- SPNS2 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs201942959, COSV100223732; called by muse, mutect2, varscan2
- STAT6 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100273422; called by muse, mutect2, varscan2
- SYN2 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV101413877; called by muse, mutect2, varscan2
- SYNE1 | c.24532G>A p.E8178K (on ENST00000367255 / NM_182961.4; = p.E8107K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99571688; called by muse, mutect2, varscan2
- TAF1L | c.5314G>A p.D1772N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV54259899; called by muse, mutect2, varscan2
- TBC1D9 | c.3581A>T p.Q1194L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV101464373; called by muse, mutect2, varscan2
- TJP1 | c.4157C>T p.P1386L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100632898; called by muse, mutect2, varscan2
- TMEM132D | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs771427502, COSV70606964; called by muse, mutect2, varscan2
- TMEM8B | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201557437, COSV100941668; called by muse, mutect2, varscan2
- TPK1 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100765939, COSV100766057; called by muse, mutect2, varscan2
- TRIP12 | c.4569G>A p.M1523I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as COSV99390639; called by muse, mutect2, varscan2
- TSGA10 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100747663; called by muse, mutect2
- TTC32 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745842151, COSV100367819; called by muse, mutect2, varscan2
- TTN | c.98548G>C p.E32850Q (on ENST00000591111; = p.E25426Q on NM_003319.4) | Missense Mutation (SNP) | VAF 41/174 reads (24%) | PolyPhen possibly damaging (0.836); catalogued as rs556218739, COSV59955733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.59477C>T p.P19826L (on ENST00000591111; = p.P12402L on NM_003319.4) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | PolyPhen benign (0.439); catalogued as COSV100620706; called by muse, mutect2, varscan2
- UBA5 | c.352T>A p.F118I | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99393305; called by muse, mutect2, varscan2
- UCP3 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368352469, COSV58368661; called by muse, mutect2, varscan2
- ULK2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100860902; called by muse, mutect2, varscan2
- UNC13C | c.635A>T p.K212M | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99520287; called by muse, mutect2, varscan2
- USP1 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV100375301, COSV60573799; called by muse, mutect2, varscan2
- USP33 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100657167; called by muse, mutect2
- USP34 | c.6188C>G p.S2063C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101277115; called by muse, mutect2, varscan2
- WDFY3 | c.4234G>T p.A1412S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV99884475; called by muse, mutect2, varscan2
- WDR4 | c.89+1G>T p.X30_splice | Splice Site (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100375317; called by muse, mutect2, varscan2
- WHRN | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs138164522, COSV99470430; called by muse, mutect2, varscan2
- WNK3 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100671685, COSV63612965; called by muse, mutect2, varscan2
- WNK4 | c.2068G>C p.E690Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99890855; called by muse, mutect2, varscan2
- XIRP1 | c.3077G>C p.G1026A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100453783, COSV61139596; called by muse, mutect2, varscan2
- XKR3 | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100509314; called by muse, mutect2, varscan2
- ZBED9 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101509264; called by muse, mutect2, varscan2
- ZFP3 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603842; called by muse, mutect2, varscan2
- ZFYVE9 | c.2264C>G p.S755* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99819262, COSV99820359; called by muse, mutect2, varscan2
- ZNF430 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.807); catalogued as COSV55108135, COSV99841881, COSV99842127; called by muse, mutect2, varscan2
- ZNF449 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100203022; called by muse, mutect2, varscan2
- ZNF536 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs769939047, COSV62822385; called by muse, mutect2, varscan2
- ZNF624 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV100257338; called by muse, mutect2, varscan2
- ZNF676 | c.729C>G p.I243M (on ENST00000650058; = p.I211M on NM_001001411.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.223); catalogued as COSV101236269; called by muse, mutect2, varscan2
- ZNF710 | c.1641C>A p.F547L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99184201; called by muse, mutect2, varscan2
- ZNF714 | c.1443C>G p.Y481* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99395407; called by muse, mutect2, varscan2
- ZSCAN5B | c.1105C>A p.Q369K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100628011; called by muse, mutect2, varscan2
- ATAD3A | c.1599dup p.R534Efs*5 | Frame Shift Ins (INS) | VAF 20/125 reads (16%) | called by mutect2, varscan2
- ATAD3A | c.1600delinsGC p.R534Afs*5 | Frame Shift Ins (INS) | VAF 21/146 reads (14%) | called by mutect2*, pindel, varscan2*
- BRINP3 | c.1508_1518del p.K503Tfs*12 | Frame Shift Del (DEL) | VAF 25/165 reads (15%) | called by mutect2, pindel, varscan2
- FAT1 | c.6019_6035del p.P2007Vfs*12 | Frame Shift Del (DEL) | VAF 40/233 reads (17%) | called by mutect2, pindel, varscan2
- MTREX | c.695del p.L232* | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- MUC5B | c.11450C>T p.A3817V | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2
- NOTCH1 | c.2051del p.G684Afs*88 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- PCF11 | c.3464del p.H1155Lfs*56 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- ADGRF4 | c.294C>G p.L98= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99348661; called by muse, mutect2, varscan2
- ARHGAP4 | c.1512C>G p.L504= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV100604117; called by muse, mutect2, varscan2
- CAVIN1 | c.684C>T p.R228= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as rs1389448827, COSV100824573; called by muse, mutect2, varscan2
- CSNK1E | c.1179C>T p.L393= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100725055; called by muse, mutect2, varscan2
- CTNNB1 | c.387A>G p.S129= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100846313; called by muse, mutect2, varscan2
- CTNS | c.132C>T p.L44= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs756058217, COSV50444275; called by muse, mutect2, varscan2
- CXCR2 | c.528G>A p.L176= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100579020; called by muse, varscan2
- CYP4B1 | c.18C>T p.L6= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1426015877, COSV99597296; called by muse, varscan2
- DCAF12L2 | c.372C>T p.D124= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV63582640; called by muse, mutect2, varscan2
- DMAP1 | c.960C>G p.V320= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100261763; called by muse, mutect2, varscan2
- DNMT1 | c.2889C>T p.P963= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as rs150359172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYD | c.2763C>A p.I921= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100929222; called by muse, mutect2, varscan2
- DYNC1LI1 | c.30C>T p.F10= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs758317039, COSV56126711, COSV99818319; called by muse, mutect2, varscan2
- EHF | c.312C>G p.L104= | Silent (SNP) | VAF 352/511 reads (69%) | catalogued as COSV99140986; called by muse, mutect2, varscan2
- FZD9 | c.960C>G p.L320= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV60671385; called by muse, mutect2, varscan2
- FZD9 | c.1116C>T p.V372= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs563536385, COSV100750874; called by muse, mutect2, varscan2
- GRP | c.393C>G p.L131= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99901027; called by muse, mutect2, varscan2
- H3C13 | c.186G>C p.L62= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100516141; called by muse, mutect2, varscan2
- HEATR4 | c.357C>T p.F119= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs150475805; called by muse, mutect2, varscan2
- HS3ST1 | c.684C>T p.I228= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV50025288; called by muse, mutect2, varscan2
- IQUB | c.2112C>A p.S704= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV100227230, COSV61237294; called by muse, mutect2, varscan2
- LRBA | c.7329G>C p.V2443= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100841913; called by muse, mutect2, varscan2
- MAP3K1 | c.522C>T p.H174= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV101267041; called by muse, mutect2, varscan2
- MPRIP | c.1566G>A p.P522= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs756692810, COSV100505977, COSV57928328; called by muse, mutect2, varscan2
- OR13A1 | c.681G>A p.V227= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV65572455; called by muse, mutect2, varscan2
- OSBPL3 | c.399C>T p.V133= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100514324; called by muse, mutect2, varscan2
- OTOF | c.4674G>T p.T1558= (on ENST00000272371 / NM_194248.3; = p.T791= on NM_004802.4) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs751556362, COSV99716836, COSV99718266; called by muse, mutect2, varscan2
- PCDHB4 | c.702C>A p.I234= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV52022136, COSV99522355; called by muse, mutect2, varscan2
- PCLO | c.2898A>G p.Q966= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100434612; called by muse, mutect2, varscan2
- PGAP1 | c.729A>T p.G243= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100698284; called by muse, mutect2, varscan2
- PIGM | c.84C>T p.A28= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV100928052; called by muse, mutect2, varscan2
- PIK3R5 | c.1875C>G p.L625= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99353614; called by muse, mutect2, varscan2
- RAB8B | c.111C>T p.F37= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV58490000; called by muse, mutect2, varscan2
- RNASE4 | c.219C>T p.F73= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV100489411; called by muse, mutect2, varscan2
- RWDD3 | c.345C>A p.L115= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99811648; called by muse, mutect2, varscan2
- SHC3 | c.1401C>A p.P467= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs146503115, COSV101011979; called by muse, mutect2, varscan2
- SKIV2L | c.2238C>T p.L746= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV100514617; called by muse, mutect2, varscan2
- SKIV2L | c.2454G>C p.L818= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100514769; called by muse, mutect2, varscan2
- SLC12A5 | c.1812G>T p.L604= (on ENST00000454036 / NM_001134771.2; = p.L581= on NM_020708.5) | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs781618113, COSV99716418; called by muse, mutect2, varscan2
- SLC1A6 | c.1551C>A p.A517= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99693978; called by muse, mutect2, varscan2
- SLC24A1 | c.327G>A p.E109= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99978458; called by muse, mutect2, varscan2
- SLC24A1 | c.1659C>T p.L553= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV99978461; called by muse, mutect2, varscan2
- SLC8A3 | c.1992C>A p.P664= (on ENST00000381269 / NM_183002.3; = p.P662= on NM_033262.4) | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV99385681; called by muse, mutect2, varscan2
- SLC8B1 | c.675C>T p.V225= | Silent (SNP) | VAF 47/216 reads (22%) | catalogued as COSV99176771; called by muse, mutect2, varscan2
- SMARCD2 | c.1374C>G p.L458= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs765772129, COSV99856528; called by muse, mutect2, varscan2
- SYT4 | c.471C>G p.L157= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99674091; called by muse, mutect2, varscan2
- TENM2 | c.990C>T p.F330= (on ENST00000518659 / NM_001122679.2; = p.F139= on NM_001080428.3) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV101319099; called by muse, mutect2, varscan2
- TRAK1 | c.537C>T p.T179= (on ENST00000327628 / NM_001349247.2; = p.T121= on NM_014965.5) | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs1559897093, COSV100410163; called by muse, mutect2, varscan2
- TRPM1 | c.615C>T p.S205= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs771401431, COSV99856245; called by muse, mutect2, varscan2
- UGT1A8 | c.759G>A p.L253= | Silent (SNP) | VAF 66/363 reads (18%) | catalogued as rs760634792, COSV100990668; called by muse, mutect2, varscan2
- UMODL1 | c.1743C>T p.L581= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs778641009, COSV61160431; called by muse, mutect2, varscan2
- VASH2 | c.966C>T p.P322= (on ENST00000517399 / NM_001301056.2; = p.P278= on NM_024749.5) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99663632; called by muse, mutect2
- VPS13D | c.2866C>T p.L956= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99167549; called by muse, mutect2, varscan2
- VWA8 | c.2394C>G p.L798= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV99864578; called by muse, mutect2, varscan2
- XK | c.616C>T p.L206= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV101064741; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1027C>T | Intron (SNP) | VAF 11/42 reads (26%) | catalogued as rs142930891; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2625C>T | Intron (SNP) | VAF 22/131 reads (17%) | catalogued as rs763851159, COSV100153891; called by muse, mutect2, varscan2
- MEIS3 | c.859-137G>C | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100520501; called by muse, mutect2
